Gene-level copy-number profile of tumor specimen TCGA-TS-A8AV-01A from TCGA case TCGA-TS-A8AV, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibrous mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 56.0 years (20,437 days).
Specimen TCGA-TS-A8AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.92a42073-3ae4-4e5d-843c-42e694127a42.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TS-A8AV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/97452c4e-f82b-49fb-98b4-97e6f794fcf1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,474; copy number 2: 57,343.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
